Somatic mutation profile of tumor specimen TCGA-55-8302-01A (aliquot TCGA-55-8302-01A-11D-2323-08) from TCGA case TCGA-55-8302, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.8 years (20,011 days).
Specimen TCGA-55-8302-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6afd19e1-f1cd-436a-ab7d-2b622d3d0e25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8302-10A (Blood Derived Normal), aliquot TCGA-55-8302-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c66bb58-dc9f-4682-815d-d253f23a0283

The open-access MAF lists 735 somatic variants for this specimen: 558 protein-altering or splice-affecting, 159 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 475, Silent 159, Nonsense Mutation 39, Splice Site 17, Frame Shift Del 16, RNA 8, Frame Shift Ins 7, Intron 5, Splice Region 3, 3'UTR 3, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF4A | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs193922479, CM064051, COSV100290926, COSV57379860, COSV57386466; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- KEAP1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50262762, COSV50266035; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AARS1 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933813; called by muse, mutect2
- ABCB1 | c.1350G>T p.M450I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV55955312; called by muse, mutect2, varscan2
- ABCC11 | c.1584C>G p.H528Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100751163; called by muse, mutect2, varscan2
- ABCD2 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 105/245 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.058); catalogued as COSV100429817; called by muse, mutect2, varscan2
- ABCG5 | c.1383G>A p.W461* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99575630; called by muse, mutect2, varscan2
- ACBD5 | c.1513C>T p.P505S (on ENST00000375888 / NM_001352568.1; = p.P496S on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101022657; called by muse, mutect2
- ACKR1 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 52/650 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63671645; called by muse, mutect2
- ACVR1C | c.1371G>T p.M457I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.211); catalogued as COSV99695073; called by muse, mutect2, varscan2
- ACVR2A | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99605176; called by muse, mutect2, varscan2
- ADA2 | c.1146C>G p.I382M (on ENST00000262607; = p.I141M on NM_177405.3) | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99376504; called by muse, mutect2, varscan2
- ADAM33 | c.342C>G p.C114W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598096; called by muse, mutect2, varscan2
- ADAMTS12 | c.3543A>T p.R1181S | Missense Mutation (SNP) | VAF 19/307 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100711714; called by muse, mutect2
- ADAMTS16 | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV56995936, COSV99943134; called by muse, mutect2
- ADAMTS20 | c.2948del p.G983Efs*12 | Frame Shift Del (DEL) | VAF 37/134 reads (28%) | catalogued as COSV67133898; called by mutect2, pindel, varscan2
- ADAMTS4 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917892; called by muse, varscan2
- ADAMTS4 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917893; called by muse, varscan2
- ADCY2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781137779, COSV57868798, COSV57902234; called by muse, mutect2, varscan2
- ADCY4 | c.2957-1G>T p.X986_splice | Splice Site (SNP) | VAF 57/192 reads (30%) | catalogued as COSV100156879; called by muse, mutect2, varscan2
- ADGRB3 | c.2191T>A p.W731R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101002008; called by muse, mutect2, varscan2
- ADGRL4 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV100875845; called by muse, mutect2, varscan2
- ADH7 | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs769630848, COSV99265474; called by muse, mutect2, varscan2
- ADRA1D | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.472); catalogued as rs1243818452, COSV101063159; called by muse, mutect2
- AFF2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 35/232 reads (15%) | catalogued as COSV99666415; called by muse, mutect2, varscan2
- AFG3L2 | c.494G>T p.R165I | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99302203; called by muse, mutect2
- AIFM3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.215); catalogued as COSV100105116; called by muse, mutect2, varscan2
- AK9 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99572792; called by muse, mutect2, varscan2
- AKAP17A | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100002511, COSV58308111; called by muse, mutect2, varscan2
- AKAP3 | c.1532A>G p.E511G | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99962648; called by muse, mutect2, varscan2
- AKAP6 | c.4301G>C p.G1434A | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.022); catalogued as COSV99804625; called by muse, mutect2, varscan2
- AKAP6 | c.4807T>A p.Y1603N | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55207232, COSV99804628; called by muse, mutect2, varscan2
- ALDH8A1 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs758165399, COSV99665033; called by muse, mutect2, varscan2
- ANAPC2 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100119248, COSV58808933; called by muse, mutect2
- ANK2 | c.3666G>T p.L1222F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004333; called by muse, mutect2, varscan2
- ANKRD12 | c.2683A>T p.K895* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100042141; called by muse, mutect2, varscan2
- ANKRD17 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV100430017; called by muse, mutect2, varscan2
- ANKS4B | c.1002T>A p.D334E | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100289959; called by muse, mutect2, varscan2
- ANO10 | c.1310T>G p.L437R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99429081; called by muse, mutect2
- ANO3 | c.2511C>A p.Y837* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as rs775363813, COSV99885888; called by muse, mutect2, varscan2
- ANXA4 | c.784-1G>T p.X262_splice | Splice Site (SNP) | VAF 28/241 reads (12%) | catalogued as rs4493288, COSV101268843; called by muse, mutect2, varscan2
- AOPEP | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as rs1248738390, COSV99469508; called by muse, mutect2, varscan2
- AP2A1 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs781118779, COSV100756523; called by muse, mutect2, varscan2
- APOB | c.8914C>A p.Q2972K | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99268219; called by muse, mutect2, varscan2
- APOL5 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV99968478; called by muse, mutect2, varscan2
- ARFGEF1 | c.2985G>T p.E995D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99144948; called by muse, mutect2, varscan2
- ARHGEF15 | c.2386G>C p.G796R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100730176; called by muse, mutect2, varscan2
- ARHGEF5 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 29/571 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1438747819; called by muse, mutect2
- ARL6IP6 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100424134; called by muse, mutect2
- ART5 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199285800, COSV99167264; called by muse, mutect2, varscan2
- ASAP1 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.956); catalogued as COSV100727915; called by muse, mutect2
- ASXL2 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs760621031, COSV55454776; called by muse, mutect2, varscan2
- ATG2B | c.821T>G p.L274* | Nonsense Mutation (SNP) | VAF 52/215 reads (24%) | catalogued as COSV100738282; called by muse, mutect2, varscan2
- ATP13A5 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100665752; called by muse, mutect2, varscan2
- ATP8B4 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467627; called by muse, mutect2, varscan2
- ATRIP | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99604194; called by muse, mutect2, varscan2
- BCAS1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs753505143, COSV65086158; called by muse, mutect2, varscan2
- BCL11A | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.04); catalogued as COSV100186582; called by muse, mutect2, varscan2
- BCORL1 | c.4465G>T p.G1489C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99501024; called by muse, mutect2, varscan2
- BDP1 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV100703562; called by muse, mutect2, varscan2
- BEND6 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.932); catalogued as COSV100876978; called by muse, mutect2, varscan2
- BPTF | c.1413G>T p.W471C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100076078; called by muse, mutect2
- BTAF1 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99795865; called by muse, mutect2
- BTNL8 | c.1298C>A p.T433K | Missense Mutation (SNP) | VAF 76/348 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99180587; called by muse, mutect2, varscan2
- BUB3 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100922285; called by muse, mutect2, varscan2
- BUD23 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99736939; called by muse, mutect2
- C10orf88 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100925049; called by muse, mutect2, varscan2
- C10orf88 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.289); catalogued as COSV100925050; called by muse, mutect2, varscan2
- C19orf57 | c.318T>A p.F106L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100694863; called by muse, mutect2, varscan2
- C20orf85 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100959383, COSV100959498; called by muse, mutect2, varscan2
- C2orf80 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100378673; called by muse, mutect2, varscan2
- C7 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV100496640; called by muse, mutect2
- C9 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.106); catalogued as COSV99662591; called by muse, mutect2, varscan2
- CACNA1E | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV62386459; called by muse, mutect2, varscan2
- CAMK2A | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV100804703; called by muse, mutect2
- CAPN3 | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV100533461; called by muse, mutect2
- CAPN3 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.186); catalogued as COSV100533465; called by muse, mutect2
- CARD11 | c.2989G>A p.G997S | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.93); catalogued as COSV101210997; called by muse, mutect2, varscan2
- CATSPER4 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128526; called by muse, mutect2
- CCDC136 | c.2797C>A p.Q933K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99923265; called by muse, mutect2, varscan2
- CCDC141 | c.3674C>G p.S1225C | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV55382199, COSV99837534; called by muse, mutect2, varscan2
- CCDC42 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1274523464, COSV99549937; called by muse, mutect2, varscan2
- CCDC80 | c.2599C>A p.L867I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99245349; called by muse, mutect2, varscan2
- CCT8L2 | c.1132A>T p.R378W | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751058032, COSV100743149, COSV63463284; called by muse, mutect2, varscan2
- CCT8L2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100743150; called by muse, mutect2, varscan2
- CD163L1 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100550689, COSV58025518; called by muse, mutect2, varscan2
- CD300A | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177998; called by muse, mutect2, varscan2
- CDH10 | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100053202; called by muse, mutect2, varscan2
- CDH12 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66461453; called by muse, mutect2
- CDH12 | c.831A>T p.K277N | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.339); catalogued as COSV66428053; called by muse, mutect2, varscan2
- CDK14 | c.506A>C p.Q169P (on ENST00000380050 / NM_001287135.2; = p.Q151P on NM_012395.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99726960; called by muse, mutect2, varscan2
- CDK14 | c.507G>T p.Q169H (on ENST00000380050 / NM_001287135.2; = p.Q151H on NM_012395.3) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99723863, COSV99726963; called by muse, mutect2, varscan2
- CDK15 | c.1199-1G>T p.X400_splice (on ENST00000652192 / NM_001366386.2; = p.X349_splice on NM_139158.2) | Splice Site (SNP) | VAF 17/123 reads (14%) | catalogued as COSV99643731; called by muse, mutect2, varscan2
- CENPK | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99669565; called by muse, mutect2, varscan2
- CEP162 | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100003442; called by muse, mutect2, varscan2
- CERKL | c.1594G>T p.V532F (on ENST00000339098 / NM_001030311.2; = p.V506F on NM_201548.5) | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as COSV100184212; called by muse, mutect2, varscan2
- CES1 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100828815; called by muse, mutect2, varscan2
- CES3 | c.1354A>T p.K452* | Nonsense Mutation (SNP) | VAF 108/469 reads (23%) | catalogued as COSV100310057; called by muse, mutect2, varscan2
- CHAT | c.1854G>T p.M618I | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.793); catalogued as COSV100340951, COSV60321199; called by muse, mutect2, varscan2
- CHD9 | c.5025G>C p.W1675C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99529770; called by muse, mutect2, varscan2
- CHST15 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.01); catalogued as rs1256939044, COSV100655375; called by muse, mutect2, varscan2
- CIC | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360324; called by muse, mutect2
- CLN8 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV58669868, COSV58670579; called by muse, mutect2
- CNTN3 | c.2446T>A p.S816T | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99726180; called by muse, mutect2, varscan2
- CNTNAP2 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs1297941346, COSV62152414; ClinVar: uncertain significance; called by muse, mutect2
- CNTNAP2 | c.3922G>T p.D1308Y | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100673259; called by muse, mutect2
- CNTNAP5 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV70516702; called by muse, mutect2, varscan2
- COL11A1 | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV62185059; called by muse, mutect2
- COL11A2 | c.2584-1G>C p.X862_splice (on ENST00000341947 / NM_080680.3; = p.X755_splice on NM_080679.2) | Splice Site (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100554394, COSV100554563; called by muse, mutect2, varscan2
- COL4A5 | c.1997G>C p.G666A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM072962, COSV100090025; called by mutect2, varscan2
- COL5A1 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880603, COSV65668041; called by muse, mutect2, varscan2
- CPA4 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99745374; called by muse, mutect2
- CRB1 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV100957750, COSV100958083; called by muse, mutect2, varscan2
- CRY1 | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV50486727, COSV99151081; called by muse, mutect2
- CSGALNACT2 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV100989856; called by muse, mutect2, varscan2
- CSMD1 | c.10565G>C p.G3522A (on ENST00000520002; = p.G3521A on NM_033225.6) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153998, COSV59344303; called by muse, mutect2, varscan2
- CSMD2 | c.1253C>A p.S418Y | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53911378; called by muse, mutect2
- CSMD3 | c.5375T>C p.I1792T (on ENST00000297405 / NM_001363185.1; = p.I1688T on NM_052900.3) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99848576; called by muse, mutect2
- CSMD3 | c.2168C>G p.S723C (on ENST00000297405 / NM_001363185.1; = p.S619C on NM_052900.3) | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99848580; called by muse, mutect2, varscan2
- CTNND2 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100481272; called by muse, mutect2
- CYLC1 | c.15G>C p.R5S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as rs763642837, COSV100255534; called by muse, mutect2, varscan2
- CYP11B1 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99455748; called by muse, mutect2, varscan2
- DACH2 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100913963; called by muse, mutect2
- DACH2 | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV64166729, COSV64176473; called by muse, mutect2, varscan2
- DCAF13 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52572303; called by muse, mutect2
- DCSTAMP | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99887009; called by muse, mutect2, varscan2
- DEFB116 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV101269253; called by muse, mutect2, varscan2
- DISP3 | c.4037C>A p.P1346H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99610033; called by muse, mutect2
- DLG5 | c.4139G>T p.G1380V | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100967904; called by muse, mutect2, varscan2
- DLGAP2 | c.465C>G p.H155Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.993); catalogued as COSV101422792; called by muse, mutect2, varscan2
- DMTF1 | c.2204C>A p.S735* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | catalogued as COSV99991525; called by muse, mutect2, varscan2
- DMXL1 | c.8486A>T p.K2829M | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100225033; called by muse, mutect2, varscan2
- DNAH5 | c.6732G>T p.K2244N | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99454471; called by muse, mutect2, varscan2
- DNAJB8 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100048505; called by muse, mutect2, varscan2
- DOCK2 | c.3848C>T p.T1283I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99915621; called by muse, mutect2, varscan2
- DPP6 | c.2459C>A p.P820Q (on ENST00000377770 / NM_001364500.2; = p.P758Q on NM_001936.5) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123882, COSV100128246; called by muse, mutect2, varscan2
- DPYS | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100680159; called by muse, mutect2
- DSP | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 22/190 reads (12%) | catalogued as COSV101131793; called by muse, mutect2, varscan2
- DST | c.19781G>A p.R6594K (on ENST00000361203 / NM_001374722.1; = p.R4291K on NM_015548.5) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99760190; called by muse, mutect2, varscan2
- DTNA | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV51991666, COSV99315515; called by muse, mutect2
- DUSP22 | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100740092; called by muse, mutect2
- DYNC1I2 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99784350; called by muse, mutect2, varscan2
- DYNC2LI1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1365297080, COSV99571604; called by muse, mutect2, varscan2
- EBF3 | c.507T>A p.S169R | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV100799633; called by muse, mutect2, varscan2
- EIPR1 | c.654-1G>T p.X218_splice | Splice Site (SNP) | VAF 19/157 reads (12%) | catalogued as COSV101182287; called by muse, mutect2, varscan2
- ENPP2 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50010042, COSV99309432; called by muse, mutect2
- ENTHD1 | c.1226C>A p.T409N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV100289149; called by muse, mutect2, varscan2
- EPAS1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341157277, COSV99763661; called by muse, mutect2, varscan2
- EPAS1 | c.2542G>C p.V848L | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV99763663; called by muse, mutect2
- EPHB1 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101214528, COSV67663093; called by muse, mutect2, varscan2
- EPPK1 | c.5390G>C p.W1797S | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101599960; called by muse, mutect2, varscan2
- ESF1 | c.2196G>T p.Q732H | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52521038; called by muse, mutect2, varscan2
- EVC2 | c.3660-1G>T p.X1220_splice | Splice Site (SNP) | VAF 43/292 reads (15%) | catalogued as COSV100186980; called by muse, mutect2, varscan2
- EXOC5 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as COSV100567295; called by muse, mutect2
- FAM135B | c.3307A>T p.K1103* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV52749380, COSV99427976; called by muse, mutect2, varscan2
- FAM47A | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV100650095, COSV100650099; called by muse, mutect2, varscan2
- FBN2 | c.8605A>G p.T2869A | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1298099024, COSV99330808; called by muse, mutect2
- FBXO28 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837491; called by muse, mutect2, varscan2
- FBXO34 | c.528A>T p.Q176H | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); catalogued as COSV100572175; called by muse, mutect2, varscan2
- FBXO34 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100572176; called by muse, mutect2, varscan2
- FCRL2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100829802, COSV100830017, COSV63833700; called by muse, mutect2
- FCRL3 | c.1402A>G p.R468G | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs753254111, COSV100943569; called by muse, mutect2
- FCRL5 | c.2815G>T p.A939S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV100709346; called by muse, mutect2, varscan2
- FCSK | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55376130, COSV99851306; called by muse, mutect2, varscan2
- FGA | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.191); catalogued as COSV100120762; called by muse, mutect2, varscan2
- FGGY | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100365959; called by muse, mutect2
- FHL1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100600867; called by muse, mutect2, varscan2
- FKBP8 | c.1030G>T p.A344S (on ENST00000222308 / NM_001308373.2; = p.A345S on NM_012181.5) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV99724287; called by muse, mutect2, varscan2
- FLG | c.7185C>A p.S2395R | Missense Mutation (SNP) | VAF 87/730 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs758617624, COSV100912250; called by muse, mutect2, varscan2
- FLG | c.3808G>T p.V1270F | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); catalogued as COSV100912253; called by muse, mutect2
- FRMPD4 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101043300, COSV101044132; called by muse, mutect2
- FSCB | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV100469924, COSV61218579; called by muse, mutect2
- FSCN3 | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99133964; called by muse, varscan2
- FSIP2 | c.19688G>T p.G6563V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100556622; called by muse, mutect2, varscan2
- G6PC | c.511A>T p.I171F | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99520987; called by muse, mutect2
- GABRA2 | c.1148T>A p.V383D | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV100734779; called by muse, mutect2, varscan2
- GABRA2 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734754; called by muse, mutect2, varscan2
- GABRB2 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99196695; called by muse, mutect2, varscan2
- GABRB3 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100161958, COSV54681840; called by muse, mutect2, varscan2
- GABRG3 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1207731681; called by muse, mutect2
- GAD2 | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 18/209 reads (9%) | catalogued as COSV52155069, COSV99394090; called by muse, mutect2
- GALNT17 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100356402; called by muse, mutect2, varscan2
- GALNT3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205018; called by muse, mutect2, varscan2
- GATAD2A | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99390754; called by muse, mutect2
- GC | c.834G>T p.L278= | Splice Region (SNP) | VAF 26/120 reads (22%) | catalogued as COSV99910186; called by muse, mutect2, varscan2
- GCSAM | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100453373; called by muse, mutect2, varscan2
- GHR | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50142547; called by muse, mutect2, varscan2
- GNAO1 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV99341821; called by muse, mutect2
- GOLGA6B | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs771311087, COSV101406955; called by muse, mutect2, varscan2
- GON4L | c.5270G>T p.W1757L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99675838; called by muse, mutect2, varscan2
- GPC5 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100996162; called by muse, mutect2, varscan2
- GPR152 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); catalogued as COSV100351680; called by muse, mutect2, varscan2
- GPR174 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV99338396; called by muse, varscan2
- GRIA1 | c.2270+1G>T p.X757_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99602496; called by muse, mutect2, varscan2
- GRIK2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100026414; called by muse, mutect2, varscan2
- GRIK2 | c.2531A>G p.Y844C | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59772793; called by muse, mutect2, varscan2
- GRM5 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.815); catalogued as COSV100554644; called by muse, mutect2, varscan2
- GRM7 | c.737-1G>T p.X246_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100736373; called by muse, mutect2, varscan2
- GRM7 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100738798; called by muse, mutect2, varscan2
- GRXCR1 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101295760; called by muse, mutect2
- GYS2 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99680280; called by muse, mutect2, varscan2
- HABP2 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100668107; called by muse, mutect2, varscan2
- HAO2 | c.132-2A>T p.X44_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100378293; called by muse, mutect2, varscan2
- HCN1 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.945); catalogued as COSV57491858; called by muse, mutect2, varscan2
- HGF | c.1174T>C p.Y392H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99738604; called by muse, mutect2, varscan2
- HGF | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55950541, COSV99738608; called by muse, mutect2
- HHATL | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99825791, COSV99825792; called by muse, mutect2, varscan2
- HLX | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775163055, COSV100854636; called by mutect2, varscan2
- HNRNPF | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100563338, COSV61560648; called by muse, mutect2, varscan2
- HOXB5 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99494759; called by muse, mutect2
- HOXD9 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99982366; called by muse, mutect2
- HPS1 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100282822; called by muse, mutect2, varscan2
- HS3ST4 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503166, COSV58813975, COSV58822361; called by muse, mutect2, varscan2
- HSD17B2 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99556515, COSV99556844; called by muse, mutect2, varscan2
- HSPA12A | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV100979968; called by muse, mutect2, varscan2
- HUWE1 | c.10684G>T p.G3562W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs782795348, COSV99474312; called by muse, mutect2, varscan2
- ICOS | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100320456; called by muse, mutect2, varscan2
- ICOS | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100320457, COSV57030200; called by muse, mutect2, varscan2
- IGFN1 | c.3477C>A p.F1159L (on ENST00000295591 / NM_001367841.1; = p.F3616L on NM_001164586.2) | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99813628; called by muse, mutect2, varscan2
- IGHV1-24 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 145/499 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568766866; called by muse, mutect2, varscan2
- IGHV4-61 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.11); catalogued as rs782219466; called by muse, mutect2
- IGKV1-16 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs768123675; called by muse, mutect2, varscan2
- IGSF1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100812348; called by muse, mutect2, varscan2
- IL16 | c.2765C>G p.S922C (on ENST00000302987 / NM_172217.5; = p.S221C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV100268182, COSV57261244; called by muse, mutect2, varscan2
- INHBC | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 145/306 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as COSV100548058; called by muse, mutect2, varscan2
- INTS12 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 46/385 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100415938; called by muse, mutect2, varscan2
- IRS1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1432435254, COSV100524990; called by muse, varscan2
- ITGAD | c.2045G>T p.R682L | Missense Mutation (SNP) | VAF 126/498 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV101210591; called by muse, mutect2, varscan2
- ITGAX | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.617); catalogued as COSV99192045; called by muse, mutect2, varscan2
- IYD | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs143034765, COSV99990120; called by muse, mutect2, varscan2
- IYD | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99990132; called by muse, mutect2, varscan2
- JPH3 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99414060; called by muse, mutect2
- KANK2 | c.2071G>T p.V691F (on ENST00000586659 / NM_001379562.1; = p.V699F on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV100763418; called by muse, mutect2, varscan2
- KCNC4 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); catalogued as rs1383051884, COSV100873693, COSV63924947; called by muse, mutect2
- KCNH5 | c.2416G>T p.G806* | Nonsense Mutation (SNP) | VAF 35/256 reads (14%) | catalogued as COSV100525445, COSV59777864; called by muse, mutect2, varscan2
- KCNU1 | c.2405C>A p.P802H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV101299439; called by muse, mutect2, varscan2
- KDM1B | c.1354G>T p.E452* (on ENST00000449850; = p.E320* on NM_153042.4) | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as COSV99924704; called by muse, mutect2, varscan2
- KDM4A | c.3053T>A p.L1018Q | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759728805, COSV99496049; called by muse, mutect2
- KIAA1109 | c.2815G>T p.G939* | Nonsense Mutation (SNP) | VAF 59/361 reads (16%) | catalogued as COSV99176889; called by muse, mutect2, varscan2
- KIF26A | c.2699G>T p.R900L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100181580; called by muse, mutect2, varscan2
- KIF2B | c.845T>A p.F282Y | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV99276279; called by muse, mutect2, varscan2
- KIF5A | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV99673607; called by muse, mutect2, varscan2
- KLHL26 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.225); catalogued as COSV99963386; called by muse, mutect2, varscan2
- KLHL3 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757829096, COSV100553585; called by muse, mutect2, varscan2
- KLK13 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 59/241 reads (24%) | catalogued as COSV50066837, COSV50067771; called by muse, mutect2, varscan2
- KRT77 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100527281, COSV59241499; called by muse, mutect2
- KRTAP21-1 | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 38/276 reads (14%) | catalogued as COSV100624986; called by muse, mutect2, varscan2
- LCE5A | c.331T>A p.C111S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV100524329; called by muse, mutect2, varscan2
- LEPR | c.1918A>G p.M640V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753680187, COSV60751931; called by muse, mutect2, varscan2
- LGR4 | c.2200A>T p.K734* | Nonsense Mutation (SNP) | VAF 17/267 reads (6%) | catalogued as COSV100156705; called by muse, mutect2
- LILRA5 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs977621950, COSV100007116; called by muse, mutect2, varscan2
- LNX1 | c.1375G>T p.V459F (on ENST00000263925 / NM_001126328.3; = p.V363F on NM_032622.2) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV55788901; called by muse, mutect2, varscan2
- LPA | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs375318299; called by muse, mutect2, varscan2
- LRFN5 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 49/471 reads (10%) | catalogued as COSV99985546; called by muse, mutect2, varscan2
- LRRC66 | c.972_973insT p.Q325Sfs*33 | Frame Shift Ins (INS) | VAF 15/99 reads (15%) | catalogued as COSV100603111; called by mutect2, pindel, varscan2
- LRRC7 | c.810G>T p.L270F (on ENST00000651989 / NM_001370785.2; = p.L237F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229972; called by muse, mutect2, varscan2
- LRRK1 | c.4478G>T p.R1493L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99443301; called by muse, mutect2, varscan2
- LRRN2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.073); catalogued as rs1283210276, COSV100912974; called by muse, mutect2
- LRRTM3 | c.1205C>A p.T402K | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100791929; called by muse, mutect2, varscan2
- LZTS1 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99743341; called by muse, mutect2, varscan2
- MAB21L4 | c.851G>C p.R284P (on ENST00000388934 / NM_001085437.3; = p.R116P on NM_024861.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as COSV100278717; called by muse, mutect2, varscan2
- MAGEB18 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428851951, COSV100305643; called by muse, mutect2
- MAGI3 | c.2824G>T p.G942C | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100290503; called by muse, mutect2
- MAP3K19 | c.3862C>A p.P1288T | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100209342; called by muse, mutect2
- MAP3K4 | c.3794G>T p.G1265V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV100815697; called by muse, mutect2, varscan2
- MAP3K5 | c.3538C>T p.L1180F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.655); catalogued as COSV100753300; called by muse, mutect2
- MAP3K7 | c.1333G>T p.V445L (on ENST00000369329 / NM_145331.3; = p.V418L on NM_003188.4) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV100997568; called by muse, mutect2, varscan2
- MAP3K7CL | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 22/183 reads (12%) | catalogued as rs1568962847, COSV99726911; called by muse, mutect2, varscan2
- MCMBP | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100750183; called by muse, mutect2, varscan2
- MCMDC2 | c.1721C>A p.T574K | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV100552340; called by muse, mutect2, varscan2
- MCTP1 | c.2571G>T p.M857I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100388242; called by muse, mutect2, varscan2
- MCU | c.280_281insT p.R94Lfs*2 | Frame Shift Ins (INS) | VAF 91/325 reads (28%) | catalogued as COSV100849274; called by mutect2, pindel, varscan2
- MEGF10 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV99175699; called by muse, mutect2, varscan2
- MFF | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100449412; called by muse, mutect2, varscan2
- MIA3 | c.2051A>G p.E684G | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV100719540; called by muse, mutect2, varscan2
- MICAL2 | c.4645A>T p.N1549Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV99812291; called by muse, mutect2, varscan2
- MKKS | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726321; called by muse, mutect2
- MKS1 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100439807; called by muse, mutect2, varscan2
- MMP2 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99528311; called by muse, mutect2, varscan2
- MUC16 | c.22327C>A p.P7443T | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.076); catalogued as COSV101201810; called by muse, mutect2, varscan2
- MXRA5 | c.4882A>T p.S1628C | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as COSV99479427; called by muse, mutect2, varscan2
- MYH1 | c.5445G>T p.Q1815H | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99876945; called by muse, varscan2
- MYO18A | c.5597A>T p.E1866V | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100572768; called by muse, mutect2, varscan2
- MYO1C | c.1144G>T p.A382S (on ENST00000648651 / NM_001080779.2; = p.A347S on NM_033375.5) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); catalogued as COSV100704567, COSV62998478; called by muse, mutect2, varscan2
- MYO3A | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781686; called by muse, mutect2
- MYO5A | c.3554G>T p.R1185L | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100698194; called by muse, mutect2, varscan2
- MYO5C | c.2869A>T p.K957* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as COSV99955534; called by muse, mutect2
- MYOM1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV99868494; called by muse, mutect2
- N4BP1 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs754172315, COSV52211855; called by muse, mutect2, varscan2
- NAT10 | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140520; called by muse, mutect2
- NCAM1 | c.2275C>A p.L759M (on ENST00000316851 / NM_181351.5; = p.L749M on NM_000615.7) | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV100378623; called by muse, mutect2
- NECTIN1 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99872667; called by muse, mutect2, varscan2
- NES | c.3577G>T p.G1193C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100958005; called by muse, mutect2
- NEUROG2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203592003, COSV100511961; called by muse, mutect2
- NID2 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV99357319; called by muse, mutect2, varscan2
- NLRP14 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV100205452; called by muse, mutect2, varscan2
- NLRP2 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as COSV99672682; called by muse, mutect2, varscan2
- NLRP5 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV101173885; called by muse, mutect2, varscan2
- NLRP8 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV52593730; called by muse, mutect2, varscan2
- NMI | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 47/210 reads (22%) | catalogued as COSV99693533; called by muse, mutect2, varscan2
- NOL4 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99305960, COSV99308523; called by muse, mutect2, varscan2
- NOS2 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as rs772704693, COSV100569902; called by muse, mutect2, varscan2
- NPAP1 | c.1887C>A p.H629Q | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.089); catalogued as COSV61511689; called by muse, mutect2, varscan2
- NPC1L1 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99213564; called by muse, mutect2, varscan2
- NPY1R | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | catalogued as COSV99649084; called by muse, mutect2, varscan2
- NR5A1 | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101007734; called by muse, mutect2, varscan2
- NRP1 | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 30/176 reads (17%) | catalogued as COSV99589650; called by muse, mutect2, varscan2
- NRXN1 | c.4391C>A p.S1464Y | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60513495, COSV60515579; called by muse, mutect2, varscan2
- NRXN1 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100456997; called by muse, mutect2, varscan2
- NT5C1B | c.487C>A p.L163M (on ENST00000359846 / NM_001199086.2; = p.L103M on NM_033253.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.26); catalogued as COSV100410305; called by muse, mutect2, varscan2
- OCA2 | c.1562T>A p.L521Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as CD112626, COSV100668725; called by muse, mutect2
- OR10G8 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101461884, COSV70908215; called by muse, mutect2, varscan2
- OR13C9 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs751298373, COSV99403567; called by muse, mutect2, varscan2
- OR1Q1 | c.905T>C p.M302T | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99939363; called by muse, mutect2, varscan2
- OR2H2 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100590088; called by muse, mutect2, varscan2
- OR2L3 | c.62G>T p.R21I | Missense Mutation (SNP) | VAF 40/723 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV63454570; called by muse, mutect2
- OR2L8 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100594327; called by muse, mutect2, varscan2
- OR4A47 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV101487114; called by muse, mutect2, varscan2
- OR4C15 | c.809C>T p.S270F (on ENST00000314644; = p.S216F on NM_001001920.2) | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV100116119; called by muse, mutect2
- OR51B5 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100332692; called by muse, mutect2
- OR51M1 | c.111C>A p.H37Q | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100150388; called by muse, mutect2, varscan2
- OR52J3 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100984947; called by muse, mutect2, varscan2
- OR5K1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs370192014, COSV60303652; called by muse, mutect2, varscan2
- OR8B3 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100660440; called by muse, mutect2, varscan2
- OR8B4 | c.719G>A p.W240* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100635836, COSV100635873; called by muse, mutect2
- OR8B4 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV62070727; called by muse, mutect2, varscan2
- OR8D1 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100766665, COSV100766680; called by muse, mutect2
- OR8I2 | c.371T>A p.I124K | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100136271, COSV56169163; called by muse, mutect2, varscan2
- OR9Q2 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100285546; called by muse, mutect2
- OSBPL6 | c.1154-1G>T p.X385_splice | Splice Site (SNP) | VAF 27/208 reads (13%) | catalogued as COSV99508557; called by muse, mutect2, varscan2
- PAK5 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100781727; called by muse, mutect2, varscan2
- PALM | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.392); catalogued as COSV99214728; called by muse, mutect2, varscan2
- PASK | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV99300281; called by muse, mutect2, varscan2
- PCDH15 | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100227983; called by muse, mutect2
- PCDH15 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227988, COSV57375009; called by muse, mutect2, varscan2
- PCDHA1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.438); catalogued as COSV100974375; called by muse, mutect2, varscan2
- PCDHA4 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV100793763; called by muse, mutect2, varscan2
- PCDHA7 | c.1657G>T p.V553L | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV100971852; called by muse, mutect2, varscan2
- PCDHGC5 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99342449; called by muse, mutect2, varscan2
- PCYOX1L | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99199295; called by muse, mutect2, varscan2
- PDE1A | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.115); catalogued as COSV100116482; called by muse, mutect2, varscan2
- PGA3 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337417; called by mutect2, varscan2
- PGLYRP2 | c.1680A>T p.R560S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.981); catalogued as COSV99484310; called by muse, mutect2, varscan2
- PHF3 | c.3022G>C p.D1008H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV100014032; called by muse, mutect2, varscan2
- PIK3CG | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as COSV100783214; called by muse, varscan2
- PIK3CG | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1346474355, COSV100783215, COSV63246347; called by muse, varscan2
- PKD1L1 | c.4756C>A p.H1586N | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99221449; called by muse, mutect2, varscan2
- PKLR | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as COSV100713038; called by muse, mutect2
- PLCB4 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); catalogued as COSV99597015; called by muse, mutect2
- PLCB4 | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99597016; called by muse, mutect2
- PLG | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | catalogued as COSV51987377, COSV99805146; called by muse, mutect2, varscan2
- POLE | c.3379-1G>T p.X1127_splice | Splice Site (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100268349; called by muse, mutect2, varscan2
- POU2F1 | c.1154G>A p.S385N (on ENST00000541643 / NM_001365848.1; = p.S408N on NM_002697.4) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99612337; called by muse, mutect2, varscan2
- PPFIA2 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV100335369; called by muse, mutect2
- PPIL2 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100622781; called by muse, mutect2, varscan2
- PPP1R3A | c.1007G>T p.R336I | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99494392; called by muse, mutect2, varscan2
- PPP1R3A | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV99494396; called by muse, mutect2, varscan2
- PPP4R4 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100429051; called by muse, mutect2, varscan2
- PRC1 | c.971-1G>A p.X324_splice | Splice Site (SNP) | VAF 40/158 reads (25%) | catalogued as COSV100727243; called by muse, mutect2, varscan2
- PRDM9 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57001961, COSV99691315; called by muse, mutect2, varscan2
- PRDM9 | c.2392C>A p.H798N | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99691316; called by muse, varscan2
- PRELP | c.531G>C p.R177S | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV100557964, COSV58117396; called by muse, mutect2, varscan2
- PRKCG | c.1479C>A p.H493Q | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99669555; called by muse, mutect2
- PROK1 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774097959, COSV99602663; called by muse, mutect2, varscan2
- PRUNE2 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943158, COSV100943332; called by muse, mutect2, varscan2
- PTCHD3 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101438972; called by muse, mutect2, varscan2
- PTGS1 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99793558; called by muse, mutect2, varscan2
- PTK2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.192); catalogued as COSV100571270; called by muse, mutect2, varscan2
- PTPRK | c.4103G>A p.G1368E (on ENST00000368215 / NM_001291984.2; = p.G1369E on NM_002844.4) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100951609; called by muse, mutect2, varscan2
- PWWP3B | c.300A>T p.R100S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100531653; called by muse, mutect2, varscan2
- RAET1G | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs775839827, COSV66274420; called by muse, mutect2, varscan2
- RBBP5 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV99196900; called by muse, mutect2, varscan2
- RBPMS2 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100264993; called by muse, mutect2, varscan2
- RDH12 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99961947; called by muse, mutect2, varscan2
- RELN | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as rs374546580, COSV100634960; called by muse, mutect2
- RETREG1 | c.321-2A>G p.X107_splice | Splice Site (SNP) | VAF 18/136 reads (13%) | catalogued as COSV100105028; called by muse, mutect2, varscan2
- RGL1 | c.2083G>C p.E695Q (on ENST00000360851 / NM_001297672.2; = p.E730Q on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100487794; called by muse, mutect2, varscan2
- RGS4 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100905614; called by muse, mutect2, varscan2
- RHBDL2 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100008699; called by muse, mutect2, varscan2
- RIMS2 | c.2636C>A p.P879Q (on ENST00000666250 / NM_001348490.2; = p.P687Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51669793, COSV99200274; called by muse, mutect2, varscan2
- RP1L1 | c.6063C>A p.D2021E | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372233185, COSV101223652; called by muse, mutect2
- RPS6KA4 | c.1954del p.R652Efs*4 | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | catalogued as COSV99590458; called by mutect2, pindel, varscan2
- RUBCNL | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs761468667, COSV100529397, COSV104402672; called by muse, mutect2, varscan2
- RYR3 | c.3563T>C p.V1188A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV101214693; called by muse, mutect2
- S100A7A | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.053); catalogued as COSV100241687; called by muse, mutect2, varscan2
- SCN11A | c.4963G>T p.E1655* | Nonsense Mutation (SNP) | VAF 60/291 reads (21%) | catalogued as COSV100182629, COSV56567488; called by muse, mutect2, varscan2
- SCN11A | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100182631; called by muse, mutect2, varscan2
- SCN1A | c.4568T>C p.I1523T (on ENST00000303395 / NM_001202435.3; = p.I1512T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as CM118323, COSV100322245; called by muse, mutect2, varscan2
- SCN2A | c.4268G>A p.G1423E | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333590; called by muse, mutect2
- SCNN1D | c.497A>T p.N166I (on ENST00000338555; = p.N330I on NM_001130413.4) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100330286; called by muse, mutect2, varscan2
- SEL1L | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV100378122; called by muse, mutect2
- SEMA5A | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101228739; called by muse, mutect2
- SEMA6D | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100317674; called by muse, mutect2, varscan2
- SERPINA10 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs533103231, COSV56228331; called by muse, mutect2, varscan2
- SERPINB4 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346016; called by muse, mutect2, varscan2
- SETD1A | c.3732G>T p.E1244D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV99353730; called by muse, mutect2, varscan2
- SGSM3 | c.1900C>A p.R634= | Splice Region (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99960699; called by muse, mutect2, varscan2
- SHC4 | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60118020; called by muse, mutect2
- SI | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as rs554208715, COSV100017275, COSV52266486; called by muse, mutect2, varscan2
- SLC12A5 | c.1681C>A p.L561M (on ENST00000454036 / NM_001134771.2; = p.L538M on NM_020708.5) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99716898; called by muse, mutect2, varscan2
- SLC16A9 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs757985427, COSV68099433; called by muse, mutect2, varscan2
- SLC17A5 | c.1093A>T p.R365* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100867161; called by muse, mutect2, varscan2
- SLC22A16 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145601305, COSV100397975; called by muse, mutect2, varscan2
- SLC22A2 | c.276C>A p.Y92* | Nonsense Mutation (SNP) | VAF 29/184 reads (16%) | catalogued as COSV100871064, COSV65267118; called by muse, mutect2, varscan2
- SLC28A1 | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as rs1010280531, COSV99723601; called by muse, mutect2, varscan2
- SLC34A1 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100184129; called by muse, mutect2, varscan2
- SLC4A10 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV99765906; called by muse, mutect2, varscan2
- SLC4A5 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100698065; called by muse, mutect2, varscan2
- SLC5A4 | c.1768+2T>A p.X590_splice | Splice Site (SNP) | VAF 16/191 reads (8%) | catalogued as COSV56672602; called by muse, mutect2
- SLC5A8 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV101610613; called by muse, mutect2, varscan2
- SLC8A1 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV60470581; called by muse, mutect2, varscan2
- SLCO1C1 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99858724; called by muse, mutect2, varscan2
- SLIT1 | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822588; called by muse, mutect2, varscan2
- SLIT2 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56597908; called by muse, mutect2, varscan2
- SLITRK1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101000076; called by muse, mutect2, varscan2
- SLITRK6 | c.2473G>T p.A825S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201371001, COSV68390205, COSV68391006; called by muse, mutect2, varscan2
- SMAD4 | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61693433; called by muse, mutect2, varscan2
- SMO | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99977131; called by muse, mutect2, varscan2
- SNAI2 | c.213T>A p.N71K | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV50078779, COSV99195025; called by muse, mutect2, varscan2
- SNRNP200 | c.4005G>T p.V1335= | Splice Region (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100108072; called by muse, mutect2, varscan2
- SNTG1 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.916); catalogued as COSV99386323; called by muse, mutect2, varscan2
- SNX29 | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100030207, COSV60053397; called by muse, mutect2, varscan2
- SORCS3 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100863847; called by muse, mutect2, varscan2
- SORCS3 | c.2287del p.E763Rfs*43 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as rs868844368, COSV63799442; called by mutect2, pindel, varscan2
- SOX6 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs745532158, COSV100322502, COSV100323324; called by muse, mutect2, varscan2
- SP5 | c.1081T>C p.C361R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935371; called by muse, mutect2, varscan2
- SPAM1 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749343447, COSV56147094, COSV99773504; called by muse, mutect2, varscan2
- SPPL2A | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99961841; called by muse, mutect2, varscan2
- SPTAN1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.176); catalogued as COSV100824037, COSV63988440; called by muse, mutect2
- SRPK1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV100644466; called by muse, mutect2, varscan2
- SRRM4 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57417285, COSV99939476; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 18/149 reads (12%) | PolyPhen probably damaging (0.988); catalogued as COSV100085467; called by muse, mutect2, varscan2
- ST8SIA6 | c.1145T>A p.L382H | Missense Mutation (SNP) | VAF 44/491 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101112112; called by muse, mutect2
- STXBP5 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV99471020; called by muse, mutect2, varscan2
- SV2A | c.1330C>G p.R444G | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100975285, COSV64965879; called by muse, mutect2, varscan2
- SVEP1 | c.8185C>A p.R2729S | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as rs202205164, COSV52835598, COSV99929868; called by muse, mutect2, varscan2
- SYCP1 | c.2854C>G p.R952G | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV101051209, COSV65696042; called by muse, mutect2, varscan2
- SYNPO2L | c.1905G>C p.Q635H (on ENST00000394810 / NM_001114133.3; = p.Q411H on NM_024875.5) | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV65739116; called by muse, mutect2, varscan2
- SYT16 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV70855036, COSV70855957; called by muse, varscan2
- TAOK1 | c.2647A>T p.M883L | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99914798; called by muse, mutect2
- TAS2R16 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV99972356; called by muse, mutect2, varscan2
- TBC1D9B | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100783671; called by muse, mutect2, varscan2
- TBX18 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100858589; called by muse, mutect2, varscan2
- TDRD5 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99677226; called by muse, mutect2, varscan2
- TENM1 | c.3427A>C p.I1143L | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV100951025; called by muse, mutect2, varscan2
- TENM3 | c.3892T>A p.Y1298N | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101305487; called by muse, mutect2, varscan2
- TEP1 | c.7656+1G>T p.X2552_splice | Splice Site (SNP) | VAF 10/126 reads (8%) | catalogued as COSV99403291; called by muse, mutect2
- TEP1 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99403293; called by muse, mutect2, varscan2
- TJP1 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100633200; called by muse, mutect2, varscan2
- TLR4 | c.2463G>T p.W821C (on ENST00000355622 / NM_138554.5; = p.W781C on NM_003266.4) | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100842875; called by muse, mutect2, varscan2
- TLR7 | c.2363C>A p.T788N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV101028155; called by muse, mutect2, varscan2
- TM2D3 | c.661G>T p.G221C (on ENST00000333202 / NM_078474.3; = p.G195C on NM_025141.3) | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309888; called by muse, mutect2
- TMEM169 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV55266962, COSV99824659; called by muse, mutect2, varscan2
- TMEM214 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as COSV99476520; called by muse, mutect2
- TMTC4 | c.1216G>A p.G406S (on ENST00000376234 / NM_001350577.2; = p.G425S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168589; called by muse, mutect2, varscan2
- TNFRSF11B | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV99816997; called by muse, mutect2, varscan2
- TNK2 | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); catalogued as rs200430444, COSV100361733, COSV57369722; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TRHR | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs1297027270, COSV100304629; called by muse, mutect2, varscan2
- TRIM21 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV99587931; called by muse, mutect2, varscan2
- TRIM32 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100529001, COSV100530478; called by muse, mutect2, varscan2
- TRPM6 | c.5360G>A p.S1787N | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV62525188; called by muse, mutect2, varscan2
- TRPV6 | c.1978G>T p.G660* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100844453, COSV63892053; called by muse, mutect2, varscan2
- TSGA10 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 32/208 reads (15%) | catalogued as COSV100747818; called by muse, mutect2, varscan2
- TSHZ3 | c.2625C>A p.D875E | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99552195, COSV99552843; called by muse, mutect2, varscan2
- TTC26 | c.1161T>A p.S387R | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100571173; called by muse, mutect2
- TTF1 | c.2600A>G p.Y867C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1373961127, COSV100524870; called by muse, mutect2, varscan2
- TTN | c.59029C>A p.P19677T (on ENST00000591111; = p.P12253T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/204 reads (13%) | PolyPhen benign (0.014); catalogued as COSV100631096; called by muse, mutect2, varscan2
- TXNIP | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs1553766115, COSV100997335; called by muse, mutect2, varscan2
- UBE2U | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.054); catalogued as COSV100934531; called by muse, mutect2, varscan2
- UGGT1 | c.2117A>G p.Y706C | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99391221; called by muse, mutect2, varscan2
- UGGT2 | c.3644G>T p.S1215I | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100948963; called by muse, mutect2, varscan2
- VIRMA | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291695147, COSV99889518; called by muse, mutect2, varscan2
- VIRMA | c.327T>A p.D109E | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99889523; called by muse, mutect2, varscan2
- VN1R2 | c.709A>C p.N237H | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV100448198; called by muse, mutect2, varscan2
- VN1R2 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100448136, COSV100448199; called by muse, mutect2, varscan2
- VN1R4 | c.483C>G p.N161K | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100237609, COSV60805568; called by muse, mutect2, varscan2
- VRK1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99388664; called by muse, mutect2, varscan2
- WASF3 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.022); catalogued as COSV100099591; called by muse, mutect2
- WASHC5 | c.3058G>C p.A1020P | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100573102; called by muse, mutect2, varscan2
- WASHC5 | c.711+1G>A p.X237_splice | Splice Site (SNP) | VAF 33/142 reads (23%) | catalogued as rs767855117, COSV100573103; called by muse, mutect2, varscan2
- WDR48 | c.2017C>A p.R673S | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100073337, COSV56530937; called by muse, mutect2, varscan2
- WDR88 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99404362; called by muse, mutect2, varscan2
- WNT7A | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV99541777; called by muse, mutect2, varscan2
- WNT8B | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.009); catalogued as rs759716710, COSV100649142; called by mutect2, varscan2
- WSCD2 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54589138, COSV99775312; called by muse, mutect2
- WT1 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100189033; called by muse, mutect2, varscan2
- XDH | c.3432G>T p.E1144D | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs200349996, COSV101052477; called by muse, mutect2, varscan2
- XIRP2 | c.6150del p.M2050Ifs*24 (on ENST00000628543; = p.M2225Ifs*24 on NM_152381.6) | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as COSV99744986; called by mutect2, varscan2
- XKR3 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100509388; called by muse, mutect2
- XPO5 | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99541460; called by muse, mutect2, varscan2
- ZAN | c.7327G>C p.V2443L | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100770383; called by muse, varscan2
- ZBP1 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV100473111, COSV100474009; called by muse, mutect2
- ZDBF2 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV100985569; called by muse, mutect2, varscan2
- ZFHX4 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99268032; called by muse, mutect2, varscan2
- ZFHX4 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99268034; called by muse, mutect2, varscan2
- ZFHX4 | c.2951A>G p.N984S | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99268035; called by muse, mutect2
- ZIC1 | c.471C>G p.N157K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV51552922, COSV99292466; called by muse, mutect2, varscan2
- ZIC3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs761644167, COSV54975368; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1214A>C p.Q405P | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); catalogued as COSV100460392; called by muse, mutect2
- ZMYND8 | c.2612A>T p.Q871L (on ENST00000311275 / NM_001363741.2; = p.Q845L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99521323; called by muse, mutect2, varscan2
- ZNF248 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100627757; called by muse, mutect2, varscan2
- ZNF257 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101448173; called by muse, mutect2, varscan2
- ZNF385D | c.440-2A>T p.X147_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | catalogued as COSV99876547; called by muse, mutect2, varscan2
- ZNF431 | c.1439G>C p.G480A | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV100219094; called by muse, mutect2
- ZNF492 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101514064; called by muse, mutect2
- ZNF518A | c.3566C>A p.S1189Y | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100283751; called by muse, mutect2, varscan2
- ZNF518B | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 52/421 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV100456891; called by muse, mutect2, varscan2
- ZNF528 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749357677, COSV100846765; called by muse, mutect2
- ZNF536 | c.1288T>A p.Y430N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1386033973, COSV100835984; called by muse, mutect2, varscan2
- ZNF547 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 23/172 reads (13%) | catalogued as COSV99988170; called by muse, mutect2, varscan2
- ZNF665 | c.648G>T p.Q216H (on ENST00000600412; = p.Q281H on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/436 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV101128827; called by muse, mutect2, varscan2
- ZNF671 | c.1534T>A p.C512S | Missense Mutation (SNP) | VAF 146/614 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766592424, COSV100235269; called by muse, mutect2, varscan2
- ZNF750 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 40/253 reads (16%) | catalogued as COSV53960359; called by muse, mutect2, varscan2
- ZNF804A | c.2203G>T p.D735Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1469525425, COSV100170305; called by muse, mutect2, varscan2
- ZNF804B | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60831186, COSV60832295; called by muse, mutect2, varscan2
- ZP3 | c.242T>A p.L81Q (on ENST00000394857 / NM_001110354.2; = p.L30Q on NM_007155.6) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV100334723; called by muse, mutect2, varscan2
- ZSCAN4 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.154); catalogued as COSV100552625; called by muse, mutect2, varscan2
- ZSWIM2 | c.1092C>A p.H364Q | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99720560; called by muse, mutect2, varscan2
- ZWILCH | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1376951491, COSV100328965; called by muse, mutect2
- ZXDB | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100886072; called by muse, mutect2, varscan2
- ADAM29 | c.1945del p.D649Tfs*6 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- ANKS1B | c.3441del p.Y1148Ifs*6 (on ENST00000547776 / NM_152788.4; = p.Y314Ifs*6 on NM_020140.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- ARNTL2 | c.1853_1860dup p.G621Kfs*22 | Frame Shift Ins (INS) | VAF 42/175 reads (24%) | called by mutect2, varscan2
- BICRA | c.2933_2949del p.G978Afs*81 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- BPIFB2 | c.109+1del | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel
- CACNA2D1 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- CCDC88A | c.664del p.H222Ifs*19 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- CENPL | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COPS6 | c.436_438del p.I146del | In Frame Del (DEL) | VAF 14/144 reads (10%) | called by pindel, varscan2
- CTTN | c.1208del p.P403Lfs*29 | Frame Shift Del (DEL) | VAF 53/239 reads (22%) | called by mutect2, pindel, varscan2
- EML5 | c.3836G>C p.C1279S | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.045); called by muse, mutect2
- FCGBP | c.3070A>T p.N1024Y | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- GPR179 | c.1390A>G p.I464V (on ENST00000621958; = p.I463V on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 22/545 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- HYDIN | c.9884G>T p.C3295F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.216); called by muse, varscan2
- HYDIN | c.9878del p.G3293Efs*7 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by pindel, varscan2
- IGHG2 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IGHV1-45 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- IGKV1-16 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 41/394 reads (10%) | called by muse, mutect2, varscan2
- ISOC1 | c.699dup p.A234Cfs*2 | Frame Shift Ins (INS) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.4015T>C p.S1339P | Missense Mutation (SNP) | VAF 179/518 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NFASC | c.646C>A p.R216S (on ENST00000339876 / NM_001378329.1; = p.R210S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- OTOS | c.169dup p.L57Pfs*75 | Frame Shift Ins (INS) | VAF 37/229 reads (16%) | called by mutect2, pindel, varscan2
- PARP8 | c.893del p.G298Afs*7 | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | called by mutect2, pindel, varscan2
- SGCB | c.704dup p.M235Ifs*6 | Frame Shift Ins (INS) | VAF 19/197 reads (10%) | called by mutect2, pindel, varscan2
- SLC2A10 | c.1288+1del | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- SLC8A1 | c.186del p.I63Ffs*33 | Frame Shift Del (DEL) | VAF 31/258 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2549G>T p.G850V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- SPPL2C | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- TAF15 | c.912T>A p.D304E (on ENST00000605844 / NM_139215.3; = p.D301E on NM_003487.4) | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- TCEA2 | c.84_88del p.M28Ifs*34 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | called by mutect2, pindel
- TCFL5 | c.1203del p.R402Gfs*22 | Frame Shift Del (DEL) | VAF 35/289 reads (12%) | called by mutect2, pindel, varscan2
- THSD7A | c.4757_4761dup p.G1588Qfs*19 | Frame Shift Ins (INS) | VAF 16/124 reads (13%) | called by mutect2, pindel, varscan2
- TMEM100 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 16/251 reads (6%) | called by muse, mutect2
- TPTE | c.932C>A p.T311N (on ENST00000618007 / NM_199261.4; = p.T293N on NM_199259.4) | Missense Mutation (SNP) | VAF 39/516 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2
- TRAV34 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCC12 | c.1356C>T p.T452= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as COSV60918237; called by muse, mutect2, varscan2
- ADGRD1 | c.1044G>T p.L348= | Silent (SNP) | VAF 31/378 reads (8%) | catalogued as COSV55454941, COSV99897140; called by muse, mutect2
- AIFM2 | c.984C>T p.F328= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100325833; called by muse, mutect2, varscan2
- AIPL1 | c.303C>A p.S101= | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- ALB | c.726C>A p.R242= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV99892353; called by muse, mutect2, varscan2
- APOF | c.93G>T p.L31= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as COSV100029149; called by muse, mutect2, varscan2
- ARMCX1 | c.264G>A p.P88= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100863247; called by muse, mutect2, varscan2
- ART3 | c.255T>C p.F85= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as COSV100587981; called by muse, mutect2, varscan2
- BMS1 | c.960T>G p.P320= | Silent (SNP) | VAF 16/264 reads (6%) | catalogued as COSV100996830; called by muse, mutect2
- C6 | c.544C>A p.R182= | Silent (SNP) | VAF 66/297 reads (22%) | catalogued as rs141862960, COSV99667835; called by muse, mutect2, varscan2
- C6 | c.399C>T p.C133= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as COSV99667838; called by muse, mutect2, varscan2
- CACNA1H | c.4188C>A p.R1396= | Silent (SNP) | VAF 53/242 reads (22%) | catalogued as COSV100673536, COSV62002526; called by muse, mutect2, varscan2
- CACNA1I | c.5946T>A p.T1982= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100361598; called by muse, mutect2
- CACNG5 | c.150C>A p.I50= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV50062864; called by muse, mutect2
- CAMSAP2 | c.2706G>A p.L902= (on ENST00000236925 / NM_001297707.2; = p.L891= on NM_203459.3) | Silent (SNP) | VAF 64/385 reads (17%) | catalogued as COSV99374369; called by muse, varscan2
- CASP2 | c.438G>A p.E146= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV100131291; called by muse, mutect2
- CCDC141 | c.1815G>T p.S605= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as COSV99837537; called by muse, mutect2, varscan2
- CCDC163 | c.57T>C p.D19= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs761350578, COSV101284478; called by mutect2, varscan2
- CCDC88A | c.5199G>A p.R1733= (on ENST00000436346 / NM_001365480.1; = p.R1705= on NM_018084.5) | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs537426993, COSV99711237; called by muse, mutect2, varscan2
- CCT8L2 | c.1326C>A p.A442= | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as COSV100743145; called by muse, mutect2, varscan2
- CDH10 | c.2130C>A p.V710= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100053201; called by muse, mutect2
- CEACAM20 | c.1758C>A p.P586= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- CHP2 | c.393C>A p.I131= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100270293; called by muse, mutect2, varscan2
- CHRND | c.774G>A p.V258= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as COSV99286157; called by muse, mutect2, varscan2
- CLCNKA | c.558G>T p.T186= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as rs1465451821, COSV100510348, COSV58890420; called by muse, mutect2, varscan2
- CPXM1 | c.1197G>T p.L399= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV101013845; called by muse, mutect2, varscan2
- CST9L | c.271C>T p.L91= | Silent (SNP) | VAF 48/298 reads (16%) | catalogued as COSV100980912; called by muse, mutect2, varscan2
- CTCFL | c.378C>A p.P126= | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as COSV99713329; called by muse, mutect2, varscan2
- DDX3X | c.981G>A p.V327= (on ENST00000399959; = p.V328= on NM_001356.5) | Silent (SNP) | VAF 107/253 reads (42%) | catalogued as COSV101302523; called by muse, mutect2, varscan2
- DHX36 | c.126C>T p.G42= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as rs768506494; called by muse, mutect2, varscan2
- DISP3 | c.978G>T p.P326= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99610028; called by muse, mutect2
- DMRTA2 | c.816C>A p.G272= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101288910; called by muse, mutect2
- DNAH3 | c.7608C>A p.T2536= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV54531348, COSV99770748; called by muse, mutect2, varscan2
- DNAH5 | c.528C>T p.L176= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV99454473; called by muse, mutect2, varscan2
- DNAH8 | c.189A>G p.L63= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as COSV100547273; called by muse, mutect2, varscan2
- DOK7 | c.561C>G p.A187= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as CD129185, COSV100403603; called by muse, mutect2, varscan2
- DRC3 | c.360G>T p.R120= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100572639, COSV100572819; called by muse, mutect2, varscan2
- EFHB | c.423G>T p.G141= | Silent (SNP) | VAF 77/195 reads (39%) | catalogued as COSV55553661; called by muse, mutect2, varscan2
- ENOX2 | c.1369C>T p.L457= (on ENST00000338144 / NM_001382520.1; = p.L428= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/292 reads (9%) | catalogued as COSV100584617, COSV57658372; called by muse, mutect2
- ENPP2 | c.885G>T p.L295= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV99309428; called by muse, mutect2
- ENPP7 | c.1185G>A p.L395= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV100093726; called by muse, mutect2
- EPAS1 | c.2544G>T p.V848= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV99763664; called by muse, mutect2
- EPG5 | c.5346G>C p.L1782= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV99958145; called by muse, mutect2, varscan2
- ESRRB | c.459G>A p.K153= | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as COSV99835836; called by muse, mutect2, varscan2
- FAM135A | c.1986T>C p.S662= (on ENST00000370479 / NM_001351599.1; = p.S449= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as COSV99526695; called by muse, mutect2, varscan2
- FAM161B | c.2091G>A p.E697= (on ENST00000651776; = p.E634= on NM_152445.3) | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV99680012; called by muse, mutect2
- FAT2 | c.11250G>C p.T3750= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV55816990, COSV99944175; called by muse, mutect2, varscan2
- FCGBP | c.9426G>T p.R3142= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2
- FCRL2 | c.1197T>A p.A399= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100830016; called by muse, mutect2
- FCSK | c.633G>T p.R211= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99851307; called by muse, mutect2, varscan2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 58/630 reads (9%) | catalogued as rs142950612; called by muse, mutect2
- FLG2 | c.6315C>T p.H2105= | Silent (SNP) | VAF 168/1201 reads (14%) | catalogued as COSV101166242; called by muse, mutect2, varscan2
- FLNC | c.4101G>A p.K1367= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as COSV100368787; called by muse, mutect2, varscan2
- FLT4 | c.63G>A p.L21= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99989136; called by muse, mutect2, varscan2
- G6PC | c.105G>T p.V35= | Silent (SNP) | VAF 34/285 reads (12%) | catalogued as COSV99520986; called by muse, mutect2, varscan2
- GALNT15 | c.9A>T p.L3= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV100328035; called by muse, mutect2, varscan2
- GLI1 | c.1254G>T p.R418= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV99954740; called by muse, mutect2, varscan2
- GRAMD1B | c.592C>A p.R198= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100455269, COSV59206704; called by muse, mutect2, varscan2
- GRIK3 | c.828C>A p.G276= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV100902364; called by muse, mutect2, varscan2
- GSTA1 | c.37C>A p.R13= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV100575615; called by muse, mutect2, varscan2
- HAP1 | c.1242G>T p.S414= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100169802, COSV57878057; called by muse, mutect2, varscan2
- HAPLN1 | c.621C>A p.A207= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV57151625, COSV99165211; called by muse, mutect2, varscan2
- HECW1 | c.1104C>A p.P368= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV101224354; called by muse, mutect2, varscan2
- HERC2 | c.9909G>A p.V3303= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as rs751705631, COSV99876858; called by muse, mutect2
- HERC2 | c.7758G>T p.V2586= | Silent (SNP) | VAF 23/266 reads (9%) | catalogued as COSV99876861; called by muse, mutect2
- HMCN1 | c.12495C>A p.V4165= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99636179; called by muse, mutect2
- HNRNPK | c.897G>T p.R299= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as COSV100699150; called by muse, mutect2
- HTR7 | c.249G>C p.V83= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV99520298; called by muse, mutect2, varscan2
- IGKV2-28 | c.114G>T p.P38= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- IGLV3-9 | c.153G>T p.V51= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs747033252; called by muse, mutect2, varscan2
- IGSF11 | c.648G>T p.V216= (on ENST00000393775 / NM_001015887.3; = p.V215= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV100677927; called by muse, mutect2, varscan2
- INTS7 | c.1782A>G p.L594= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV100877580; called by muse, mutect2, varscan2
- JPH3 | c.264G>A p.T88= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99414059; called by muse, mutect2, varscan2
- KATNIP | c.3912C>A p.A1304= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV55173731, COSV99852052; called by muse, mutect2, varscan2
- KBTBD8 | c.414A>G p.Q138= | Silent (SNP) | VAF 65/333 reads (20%) | catalogued as rs766430559, COSV55129100; called by muse, mutect2, varscan2
- KCND2 | c.807C>A p.A269= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV100478779; called by muse, mutect2
- KDR | c.3285G>C p.L1095= | Silent (SNP) | VAF 46/252 reads (18%) | catalogued as COSV99818763; called by muse, mutect2, varscan2
- KLHL32 | c.738G>T p.L246= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as COSV100987505; called by muse, mutect2, varscan2
- LAMA1 | c.5343G>A p.L1781= | Silent (SNP) | VAF 30/218 reads (14%) | catalogued as COSV101057823; called by muse, mutect2, varscan2
- LAMA2 | c.7656G>A p.L2552= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as rs764506187, COSV101370860; called by muse, mutect2, varscan2
- LAMC3 | c.2118C>T p.P706= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as COSV100736099; called by muse, mutect2, varscan2
- LARS1 | c.255G>T p.L85= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV99198887; called by muse, mutect2, varscan2
- LGI1 | c.915C>G p.G305= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as COSV101004488; called by muse, mutect2, varscan2
- LIFR | c.1248G>T p.L416= | Silent (SNP) | VAF 12/287 reads (4%) | catalogued as COSV99665584; called by muse, mutect2
- LILRA2 | c.1173G>T p.G391= | Silent (SNP) | VAF 86/302 reads (28%) | catalogued as COSV99253976; called by muse, mutect2, varscan2
- LILRB1 | c.912C>A p.L304= (on ENST00000427581; = p.L268= on NM_006669.6) | Silent (SNP) | VAF 39/241 reads (16%) | catalogued as COSV100207939; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.198C>T p.P66= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99524193; called by muse, mutect2, varscan2
- LMBRD1 | c.1506A>C p.T502= (on ENST00000649011; = p.T480= on NM_018368.4) | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100992718; called by muse, mutect2, varscan2
- LRRC25 | c.123G>T p.T41= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100170629; called by muse, mutect2, varscan2
- LSS | c.255G>A p.V85= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV100711062; called by muse, mutect2, varscan2
- MAGI2 | c.2526C>A p.I842= | Silent (SNP) | VAF 30/289 reads (10%) | catalogued as COSV100833270, COSV100836714; called by muse, mutect2, varscan2
- MAN2B2 | c.2079G>T p.G693= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV99578110; called by muse, mutect2, varscan2
- NBEA | c.1768T>C p.L590= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100084488; called by muse, mutect2, varscan2
- NKD2 | c.694C>A p.R232= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56890844, COSV99724437; called by muse, mutect2, varscan2
- OR10G8 | c.816C>T p.A272= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as rs375452777; called by muse, mutect2
- OR10J1 | c.327C>T p.I109= | Silent (SNP) | VAF 41/193 reads (21%) | catalogued as COSV101420040; called by muse, mutect2, varscan2
- OR14A16 | c.885G>A p.K295= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100713872, COSV62926005; called by muse, mutect2, varscan2
- OR14I1 | c.723C>T p.P241= | Silent (SNP) | VAF 33/223 reads (15%) | catalogued as COSV100700542; called by muse, mutect2, varscan2
- OR2F1 | c.735C>A p.L245= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as COSV101231336; called by muse, mutect2
- OR2H2 | c.807C>A p.G269= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- OR2M7 | c.438C>A p.A146= | Silent (SNP) | VAF 96/679 reads (14%) | catalogued as rs960556956, COSV100522704; called by muse, mutect2, varscan2
- OR52N1 | c.888G>T p.G296= | Silent (SNP) | VAF 66/291 reads (23%) | catalogued as COSV100398736; called by muse, mutect2, varscan2
- OR5D16 | c.534T>C p.H178= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as rs1274306306, COSV101004150; called by muse, mutect2, varscan2
- OR6B2 | c.501G>C p.T167= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99401771; called by muse, mutect2, varscan2
- PAMR1 | c.1008A>T p.S336= (on ENST00000619888 / NM_001001991.3; = p.S353= on NM_015430.4) | Silent (SNP) | VAF 17/258 reads (7%) | catalogued as COSV99553340; called by muse, mutect2
- PCDHA3 | c.1551G>T p.V517= | Silent (SNP) | VAF 66/237 reads (28%) | catalogued as COSV100793762, COSV63540537; called by muse, mutect2, varscan2
- PCDHB10 | c.156G>T p.L52= | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV99505063; called by muse, mutect2, varscan2
- PDE6C | c.1095T>C p.P365= | Silent (SNP) | VAF 74/277 reads (27%) | catalogued as COSV101008861; called by muse, mutect2
- PDZRN3 | c.777G>T p.L259= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99732214; called by muse, mutect2
- PHF24 | c.246C>A p.L82= | Silent (SNP) | VAF 109/266 reads (41%) | catalogued as COSV54277148; called by muse, mutect2, varscan2
- PMPCA | c.174A>T p.T58= | Silent (SNP) | VAF 45/302 reads (15%) | catalogued as COSV100048408; called by muse, mutect2, varscan2
- PRAG1 | c.4053G>T p.L1351= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV100422872; called by muse, mutect2, varscan2
- PSMD1 | c.948A>T p.P316= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100433908; called by muse, mutect2
- PTGDR | c.459C>A p.A153= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as COSV100035742; called by muse, mutect2, varscan2
- RBFOX1 | c.1003C>A p.R335= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs1312108862, COSV100303712, COSV60948993, COSV60949190; called by muse, mutect2, varscan2
- RBM4B | c.198C>T p.N66= | Silent (SNP) | VAF 105/438 reads (24%) | catalogued as rs757657617, COSV59497261; called by muse, mutect2, varscan2
- RELN | c.6090G>C p.S2030= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100634959; called by muse, mutect2
- RET | c.876G>A p.V292= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100394683; called by muse, mutect2, varscan2
- RIMS2 | c.99G>A p.T33= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs866013254, COSV68498472; called by muse, mutect2, varscan2
- RIN2 | c.1992C>T p.H664= (on ENST00000255006 / NM_001242581.1; = p.H615= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99657936; called by muse, mutect2
- RPH3A | c.1443C>A p.S481= (on ENST00000389385 / NM_001143854.2; = p.S477= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/335 reads (32%) | catalogued as COSV101231898; called by muse, mutect2, varscan2
- RYR2 | c.1665C>T p.L555= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs371262363; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAP30L | c.433C>A p.R145= | Silent (SNP) | VAF 57/326 reads (17%) | catalogued as COSV99770485; called by muse, mutect2, varscan2
- SCGB1A1 | c.117C>T p.P39= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs763990264, COSV99545954; called by muse, mutect2, varscan2
- SCN5A | c.2247G>A p.L749= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV100350714; called by muse, mutect2, varscan2
- SDK2 | c.1659C>G p.S553= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101168705; called by muse, mutect2, varscan2
- SEZ6 | c.2481C>A p.A827= | Silent (SNP) | VAF 99/391 reads (25%) | catalogued as COSV100253582; called by muse, mutect2, varscan2
- SEZ6L | c.2688C>A p.S896= | Silent (SNP) | VAF 36/178 reads (20%) | catalogued as COSV99961010, COSV99962987; called by muse, mutect2, varscan2
- SLC23A2 | c.801G>T p.G267= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV100595326; called by muse, mutect2
- SLC2A5 | c.1248C>A p.G416= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2
- SLC30A3 | c.873C>A p.I291= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99273909; called by muse, mutect2, varscan2
- SLC35C2 | c.147G>T p.T49= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV54758368, COSV99709605; called by muse, mutect2, varscan2
- SLC45A2 | c.1491G>A p.L497= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs1416311534, COSV56876892; called by muse, mutect2, varscan2
- SLC6A2 | c.1764G>A p.L588= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV99574651; called by muse, mutect2, varscan2
- SLITRK5 | c.1089C>T p.A363= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV61524507; called by muse, mutect2, varscan2
- SOCS5 | c.546G>A p.Q182= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as COSV100125510; called by muse, mutect2, varscan2
- SPATA31A1 | c.2880C>A p.V960= | Silent (SNP) | VAF 108/303 reads (36%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1656C>A p.S552= | Silent (SNP) | VAF 42/270 reads (16%) | catalogued as COSV100351093; called by muse, mutect2, varscan2
- SPTA1 | c.1716C>T p.A572= | Silent (SNP) | VAF 62/380 reads (16%) | catalogued as COSV100935617; called by muse, mutect2, varscan2
- SSTR4 | c.486G>T p.V162= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as COSV99658815; called by muse, mutect2
- STIM1 | c.414A>T p.V138= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100331038; called by muse, mutect2, varscan2
- SYT10 | c.828T>A p.L276= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV57346629, COSV99952022; called by muse, mutect2
- TBC1D32 | c.2133C>T p.F711= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs762480518, COSV99251358; called by muse, mutect2, varscan2
- TIE1 | c.2196A>G p.V732= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as COSV100992205; called by muse, mutect2, varscan2
- TMEM139 | c.108C>A p.T36= | Silent (SNP) | VAF 41/321 reads (13%) | catalogued as COSV100131289; called by muse, mutect2, varscan2
- TMTC2 | c.2355G>T p.L785= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100338892; called by muse, mutect2, varscan2
- TNKS2 | c.1491G>T p.L497= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100861163; called by muse, mutect2
- TNKS2 | c.2571A>T p.S857= | Silent (SNP) | VAF 11/228 reads (5%) | catalogued as COSV100861164; called by muse, mutect2
- TNNT2 | c.345G>T p.L115= | Silent (SNP) | VAF 40/283 reads (14%) | catalogued as COSV99372544; called by muse, varscan2
- TRAV24 | c.78G>T p.V26= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- TRIM39 | c.282C>G p.L94= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100935925; called by muse, mutect2, varscan2
- TRIM75P | c.282C>A p.T94= | Silent (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- UGT2A1 | c.1167G>A p.V389= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV99684922; called by muse, mutect2, varscan2
- ZBTB17 | c.1767C>T p.S589= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs777619590, COSV100999067, COSV65270670; called by muse, mutect2
- ZFHX3 | c.1620C>G p.L540= | Silent (SNP) | VAF 36/178 reads (20%) | catalogued as COSV99214792; called by muse, mutect2, varscan2
- ZFHX4 | c.7596C>A p.P2532= | Silent (SNP) | VAF 45/241 reads (19%) | catalogued as COSV99268037; called by muse, mutect2, varscan2
- ZNF496 | c.1020G>T p.P340= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as COSV99666220; called by muse, mutect2, varscan2
- ZNF501 | c.168A>T p.G56= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV101247160, COSV68516279, COSV68516668; called by muse, mutect2, varscan2
- ZNF827 | c.1509G>T p.T503= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV101061771; called by muse, mutect2, varscan2
- AK5 | c.699+15887G>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100481512, COSV100481578; called by muse, mutect2
- C3orf35 | chr3:37417426 G>T | 3'Flank (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2, varscan2
- C8orf31 | n.553C>T | RNA (SNP) | VAF 12/74 reads (16%) | catalogued as rs1366359802; called by muse, mutect2, varscan2
- CDK15 | c.1009+5825G>T | Intron (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99643730; called by muse, mutect2, varscan2
- CFAP46 | c.966+113G>T | Intron (SNP) | VAF 27/156 reads (17%) | catalogued as COSV100886831; called by muse, mutect2, varscan2
- DEFB119 | c.61+1267C>T | Intron (SNP) | VAF 29/212 reads (14%) | catalogued as rs190164254, COSV59267138; called by muse, mutect2, varscan2
- HERC2P3 | n.846C>A | RNA (SNP) | VAF 86/258 reads (33%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1189C>T | 3'UTR (SNP) | VAF 21/143 reads (15%) | catalogued as rs1397805990, COSV100739352; called by muse, mutect2, varscan2
- MIR17 | n.28_32del | RNA (DEL) | VAF 29/214 reads (14%) | called by mutect2, pindel, varscan2
- MIR518F | n.16C>A | RNA (SNP) | VAF 63/272 reads (23%) | called by muse, mutect2, varscan2
- MIR548A1 | n.69G>T | RNA (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- MIR99A | n.57G>T | RNA (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- NEK7 | c.198+3308A>T | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs986937836, COSV100954491; called by muse, mutect2
- RRP7A | c.*3831T>A | 3'UTR (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- SLC36A2 | c.*2C>T | 3'UTR (SNP) | VAF 29/116 reads (25%) | catalogued as COSV100079458; called by muse, mutect2, varscan2
- SNORD114-15 | n.30G>T | RNA (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- VN1R10P | n.430C>T | RNA (SNP) | VAF 47/279 reads (17%) | called by muse, mutect2, varscan2
- ZNF207 | c.-101G>T | 5'UTR (SNP) | VAF 60/316 reads (19%) | catalogued as COSV100340707; called by muse, mutect2, varscan2
